Somatic mutation profile of tumor specimen TCGA-06-0192-01B (aliquot TCGA-06-0192-01B-01D-1492-08) from TCGA case TCGA-06-0192, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.2 years (21,243 days).
Specimen TCGA-06-0192-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b1830c8-ab28-48c2-84c9-4ad86495d77d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0192-10A (Blood Derived Normal), aliquot TCGA-06-0192-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bb0a596-b16d-4456-8777-5644b9945708

The open-access MAF lists 72 somatic variants for this specimen: 49 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 20, Nonsense Mutation 7, Splice Site 2, Frame Shift Ins 2, RNA 1, Frame Shift Del 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.945T>A p.Y315* | Nonsense Mutation (SNP) | VAF 39/84 reads (46%) | catalogued as rs876661058, CM033670, CM981676, COSV64295157, COSV64301587; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.748del p.A250Lfs*4 | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | catalogued as rs955978982, COSV55957292; called by mutect2, varscan2
- ABCC9 | c.2546A>G p.H849R | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV53968830; called by muse, mutect2, varscan2
- ADGRL4 | c.743C>A p.T248K | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.259); catalogued as rs1490356044, COSV66061144, COSV66066625; called by muse, mutect2, varscan2
- AGPAT1 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV61247456; called by muse, mutect2, varscan2
- AMER3 | c.1525G>A p.V509I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs369736958; called by muse, mutect2, varscan2
- ARNTL2 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 36/113 reads (32%) | catalogued as rs1222363590, COSV53824344, COSV53825144; called by muse, mutect2, varscan2
- ASB8 | c.387C>A p.N129K | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.247); catalogued as COSV56656943; called by muse, mutect2, varscan2
- CDK17 | c.874-1G>C p.X292_splice | Splice Site (SNP) | VAF 19/90 reads (21%) | catalogued as COSV54128381; called by muse, mutect2, varscan2
- CLEC1A | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV59531653; called by muse, mutect2, varscan2
- CTR9 | c.127A>G p.I43V | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV63728411; called by muse, mutect2
- CYBB | c.1140G>A p.W380* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as CM106227, COSV66084909; called by muse, mutect2, varscan2
- DDI1 | c.506A>C p.E169A | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV56375348; called by muse, mutect2, varscan2
- FGD6 | c.1678C>T p.R560W | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs149076340; called by muse, mutect2, varscan2
- FLACC1 | c.1184T>G p.I395S | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV51849447; called by muse, mutect2, varscan2
- FOXJ3 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 58/217 reads (27%) | catalogued as COSV62361884; called by muse, mutect2, varscan2
- GABRB3 | c.709T>C p.F237L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54660563; called by muse, mutect2, varscan2
- GAL3ST1 | c.1193T>G p.I398S | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58892362; called by muse, mutect2, varscan2
- GOLGA4 | c.5660T>G p.L1887* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV62710353; called by muse, mutect2, varscan2
- GPR174 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as COSV52131430; called by muse, mutect2, varscan2
- GRIN2A | c.3191C>T p.T1064M | Missense Mutation (SNP) | VAF 89/373 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs756930722, COSV58029562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HIPK2 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762809580, COSV61227004, COSV61229041; called by muse, mutect2, varscan2
- HLA-F | c.278A>G p.Q93R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.625); catalogued as COSV52575274; called by muse, mutect2, varscan2
- HOXB13 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs1466480316, COSV51704525; called by muse, varscan2
- KEL | c.223+1G>A p.X75_splice | Splice Site (SNP) | VAF 33/150 reads (22%) | catalogued as rs369569464, CS012497, CS012498; called by muse, mutect2, varscan2
- KRTAP10-3 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs587776082, COSV100552310, COSV59959098; called by muse, mutect2, varscan2
- LCE1F | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.005); catalogued as rs765145222, COSV57668783, COSV57669150; called by muse, mutect2, varscan2
- MAPK13 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs776053641, COSV52982806; called by muse, mutect2, varscan2
- MDGA2 | c.1436C>T p.T479M (on ENST00000399232 / NM_001113498.2; = p.T181M on NM_182830.4) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs762117148, COSV62087901, COSV62110860; called by mutect2, varscan2
- MECR | c.47A>C p.Q16P | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV55285040; called by muse, mutect2, varscan2
- MX2 | c.1672G>A p.V558M | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV58096142; called by muse, mutect2, varscan2
- NF1 | c.7330dup p.T2444Nfs*4 (on ENST00000358273 / NM_001042492.3; = p.T2423Nfs*4 on NM_000267.3) | Frame Shift Ins (INS) | VAF 17/57 reads (30%) | catalogued as rs1064794278, CI992571; called by mutect2, pindel, varscan2
- OR2B2 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV57579476; called by muse, mutect2
- OR5F1 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV53545689; called by muse, varscan2
- OR9G1 | c.434C>A p.A145E | Missense Mutation (SNP) | VAF 46/387 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV56449995; called by muse, mutect2, varscan2
- PGR | c.348C>G p.D116E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV54800102; called by muse, mutect2
- PLCG1 | c.3014G>A p.R1005Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.277); catalogued as rs768105603, COSV54817677; called by muse, mutect2, varscan2
- RTL3 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as rs148985625, COSV58183919; called by muse, varscan2
- SMARCC2 | c.2593G>A p.A865T | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1292823810, COSV57217320; called by muse, mutect2, varscan2
- SNX9 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as COSV67583912; called by muse, mutect2, varscan2
- TAT | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs774749746, COSV63532262, COSV63533172; called by muse, mutect2, varscan2
- TDRD6 | c.3138T>A p.D1046E | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60175165; called by muse, mutect2, varscan2
- TMEM174 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); catalogued as rs779212422, COSV57113581; called by muse, mutect2, varscan2
- TMPRSS15 | c.2858A>T p.N953I | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53038562; called by muse, mutect2, varscan2
- TOMM40L | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.698); catalogued as COSV63467661; called by muse, mutect2, varscan2
- TPP1 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1266615275, COSV54993924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WWC1 | c.2340G>A p.W780* | Nonsense Mutation (SNP) | VAF 30/133 reads (23%) | catalogued as COSV54649723; called by muse, mutect2
- ZNF430 | c.578A>G p.N193S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV55109003; called by muse, mutect2, varscan2
- PCM1 | c.5718dup p.R1907Tfs*4 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- ATP13A4 | c.2289G>A p.E763= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs750367072, COSV61319246; called by mutect2, varscan2
- CHRM3 | c.525G>A p.T175= | Silent (SNP) | VAF 87/283 reads (31%) | catalogued as rs746065076, COSV55087039, COSV55090492; called by muse, mutect2, varscan2
- CYP4F3 | c.1416G>A p.A472= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as rs1568404701, COSV55409135; called by muse, mutect2, varscan2
- HECW2 | c.1737C>T p.G579= | Silent (SNP) | VAF 32/123 reads (26%) | catalogued as rs111271189; called by muse, mutect2, varscan2
- HERPUD1 | c.447G>A p.Q149= | Silent (SNP) | VAF 34/383 reads (9%) | catalogued as rs1038205994, COSV55861589; called by muse, mutect2
- LRP4 | c.5538C>T p.D1846= | Silent (SNP) | VAF 16/148 reads (11%) | catalogued as rs769171471, COSV66135370; called by muse, mutect2, varscan2
- LUZP2 | c.501G>C p.G167= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV61201982; called by muse, mutect2, varscan2
- MAS1L | c.75C>G p.L25= | Silent (SNP) | VAF 9/171 reads (5%) | catalogued as COSV65808817; called by muse, mutect2
- NKAP | c.15C>T p.S5= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV65056146; called by muse, mutect2, varscan2
- OR2T3 | c.594C>T p.S198= | Silent (SNP) | VAF 14/232 reads (6%) | catalogued as COSV100612983, COSV62082222; called by muse, mutect2
- OR8G5 | c.117G>T p.V39= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV100422419; called by muse, mutect2, varscan2
- OVOL2 | c.657C>T p.C219= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as rs772646157, COSV53860162; called by muse, mutect2, varscan2
- PCDHGB4 | c.1539C>T p.F513= | Silent (SNP) | VAF 50/226 reads (22%) | catalogued as COSV53932343; called by muse, mutect2, varscan2
- PRUNE2 | c.4260C>T p.S1420= | Silent (SNP) | VAF 25/153 reads (16%) | catalogued as rs768828405, COSV65040690; called by muse, mutect2, varscan2
- TRPM8 | c.1563C>A p.L521= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV61221739; called by muse, mutect2, varscan2
- TTBK2 | c.3291C>T p.V1097= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs774600774, COSV51159522; called by muse, mutect2, varscan2
- USP50 | c.15G>A p.P5= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as rs755371001, COSV73213908; called by muse, mutect2, varscan2
- UTP25 | c.597A>G p.K199= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV71965884; called by muse, mutect2, varscan2
- WASHC2C | c.2031C>T p.A677= | Silent (SNP) | VAF 51/328 reads (16%) | catalogued as COSV60491020; called by muse, mutect2, varscan2
- ZIC2 | c.624G>A p.A208= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV66254910; called by muse, mutect2, varscan2
- AP2A2 | c.*447C>T | 3'UTR (SNP) | VAF 9/28 reads (32%) | catalogued as rs771901429, COSV100172927; called by muse, mutect2, varscan2
- FAM183BP | n.1249G>A | RNA (SNP) | VAF 117/467 reads (25%) | catalogued as rs755459118; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-51545G>A | Intron (SNP) | VAF 5/17 reads (29%) | catalogued as rs1044931562, COSV67440801; called by muse, mutect2, varscan2
